Somatic mutation profile of tumor specimen TCGA-SH-A7BC-01A (aliquot TCGA-SH-A7BC-01A-11D-A34C-32) from TCGA case TCGA-SH-A7BC, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 67.0 years (24,459 days).
Specimen TCGA-SH-A7BC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4d2d3b6-bfd3-4465-a3ec-416b8f9fe4a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SH-A7BC-10A (Blood Derived Normal), aliquot TCGA-SH-A7BC-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/562638a6-b0ab-4417-abbe-86f5e947273e

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 17, Silent 7, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DPPA4 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1312664887; called by muse, mutect2, varscan2
- EGR4 | c.545G>A p.G182D (on ENST00000545030; = p.G79D on NM_001965.4) | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as rs1389501015, COSV71532330; called by muse, mutect2, varscan2
- EXOC8 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV50480335; called by muse, mutect2, varscan2
- GIT1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1000500862; called by muse, mutect2, varscan2
- INPPL1 | c.2525A>G p.K842R | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs749358400; called by muse, mutect2, varscan2
- LY6G6C | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.725); catalogued as rs1004934858; called by muse, mutect2, varscan2
- MAP3K3 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.1); catalogued as COSV62280992; called by muse, mutect2, varscan2
- TGFBR2 | c.264-1G>A p.X88_splice | Splice Site (SNP) | VAF 37/125 reads (30%) | catalogued as COSV55464113; called by muse, mutect2, varscan2
- CRACD | c.1988C>T p.S663F | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- DMTF1 | c.536A>G p.D179G | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, varscan2
- FAT4 | c.1376C>A p.A459E | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- FN1 | c.2810A>G p.Y937C | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSH4 | c.2362A>G p.T788A | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); called by muse, mutect2
- PCDHGB1 | c.804G>C p.E268D | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- PDZD2 | c.4635G>C p.E1545D | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- TUFT1 | c.959A>G p.D320G | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WNT1 | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZC3H12B | c.2386T>A p.Y796N | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CASD1 | c.1416G>A p.G472= | Silent (SNP) | VAF 35/107 reads (33%) | called by muse, mutect2, varscan2
- CRACD | c.1989C>T p.S663= | Silent (SNP) | VAF 45/138 reads (33%) | catalogued as rs190006805, COSV51715841; called by muse, mutect2, varscan2
- HEYL | c.273G>A p.T91= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as rs776350380, COSV65721674; called by muse, mutect2, varscan2
- NAV1 | c.4692G>A p.K1564= | Silent (SNP) | VAF 45/177 reads (25%) | catalogued as rs1370513346; called by muse, mutect2, varscan2
- SLC43A2 | c.639C>G p.V213= | Silent (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- TMEM123 | c.18A>C p.R6= | Silent (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- WBP11 | c.1350C>T p.L450= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs1441339651; called by muse, mutect2, varscan2
